CPTAC case C3L-07438 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/88f54acc-2a39-409a-bb4b-17eeea0d59c7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1942; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.5 years (29,050 days); Year of diagnosis: 2021; Days to last known disease status: 4 days; Days to last follow up: 4 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 4.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Biospecimens (5 samples)
- Samples C3L-07438-50, C3L-07438-51, C3L-07438-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-07438-61, C3L-07438-62 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
